Gene-level copy-number profile of tumor specimen C3N-03797-01 (profiled together with C3N-03797-02, C3N-03797-03) from CPTAC case C3N-03797, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.5 years (26,114 days).
Specimen C3N-03797-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9d7b48c5-c09a-432a-b70b-e492c3101f5f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03797-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/6cc5b2df-ccd1-41b7-a66f-1b9b4dd96fda

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 12,784; copy number 2: 44,308; copy number 3: 1,296; copy number 4: 5; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:116,775,104–116,775,623, 1 gene, copy number 5: FTH1P22.
- chr2:130,459,455–130,509,707, 1 gene, copy number 5 (within-gene range 2–5): POTEI.
- chr15:21,148,334–21,167,357, 2 genes, copy number 5: AC126335.2, BMS1P16.

Autosomal genes at a single copy (total copy number 1): 10,441. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
